Gene-level copy-number profile of tumor specimen TCGA-XF-A9SX-01A from TCGA case TCGA-XF-A9SX, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 63.9 years (23,349 days).
Specimen TCGA-XF-A9SX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.63e62204-8712-4884-be7a-7aa6acc6d54a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XF-A9SX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/24f1ce6c-8469-45de-8dc3-25c55257ad24

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 432; copy number 2: 6,970; copy number 3: 13,712; copy number 4: 32,573; copy number 5: 3,153; copy number 6: 1,433; copy number 7: 955; copy number 8: 355; copy number 9: 39; copy number 10: 79; copy number 11: 43; copy number 15: 11; copy number 19: 22; copy number 31: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-A9SX-01A-21D-A390-01): tumor purity 0.5, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 229 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:110,590,082–114,693,772, 39 genes, copy number 9 (within-gene range 5–9): AC073326.2, IMMP2L, AC073326.1, LRRN3, AC003989.2, AC003989.1, DOCK4, AC003077.1, DOCK4-AS1, RNA5SP237, AC003080.1, ZNF277, RN7SKP187, AC004112.1, MTND5P8, MTND6P24, MTCYBP24, IFRD1, AC079741.1, AC005192.1, AC079741.2, LSMEM1, NPM1P14, AC002463.1, MIPEPP1, TMEM168, BMT2, HRAT17, AC073346.2, GPR85, AC073346.1, SMIM30, AC073137.1, AC073348.1, AC073348.2, PPP1R3A, FOXP2, AC073626.2, AC073626.1.
- chr10:73,742,995–76,836,861, 64 genes, copy number 11–19 (broad region; genes not listed).
- chr10:76,888,044–76,980,624, 1 gene, copy number 11: KCNMA1-AS1.
- chr11:31,280,672–32,104,665, 11 genes, copy number 15 (within-gene range 6–15): CYCSP25, AL137804.1, DNAJC24, IMMP1L, ELP4, AC131571.1, PAX6, PAUPAR, AL035078.4, AL035078.1, AL035078.3.
- chr17:19,495,385–19,579,034, 1 gene, copy number 31 (within-gene range 2–31): SLC47A1.
- chr17:19,557,211–21,641,536, 113 genes, copy number 10–31 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 432. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
